Gene-level copy-number profile of tumor specimen TCGA-VP-AA1N-01A from TCGA case TCGA-VP-AA1N, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 70.6 years (25,781 days).
Specimen TCGA-VP-AA1N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.e18bc3f3-bbdb-4abc-88e4-5a169031448a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VP-AA1N-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f008e989-90c8-4888-b5bf-0564a64828bd

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 83; copy number 1: 928; copy number 2: 5,820; copy number 3: 19,783; copy number 4: 28,707; copy number 5: 1,945; copy number 6: 2,551.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VP-AA1N-01A-31D-A41J-01): tumor purity 0.54, ploidy 3.62, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 60 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:119,302,225–119,372,560, 2 genes: C2orf76, DBI.
- chr2:139,982,684–140,220,368, 4 genes: RN7SL283P, LINC01853, MTCO1P44, MTND2P19.
- chr10:87,659,613–87,863,533, 5 genes (within-gene range 0–1): PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN.
- chr13:62,212,577–68,634,486, 49 genes: LINC01075, LINC01074, LINC00459, RPL32P28, AL356102.1, SQSTM1P1, AL445668.1, LINC00448, AL354810.1, LINC00376, AL359208.1, LINC00395, OR7E156P, AL445989.2, AL445989.1, RNU6-81P, PPP1R2P10, AL445238.2, OR7E104P, AL445238.1, LINC00355, NFYAP1, LGMNP1, STARP1, HNRNPA3P5, LINC01052, AL158038.1, MIR548X2, MIR4704, TRIM60P19, PCDH9, PCDH9-AS1, RNU7-87P, PCDH9-AS2, PCDH9-AS3, PCDH9-AS4, AL160254.1, RPSAP53, LINC00364, AL512452.1, BCRP9, NPM1P22, OR7E111P, OR7E33P, AL590027.1, ELL2P3, HNRNPA1P18, RPL37P21, RPS3AP52.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 928. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
